Somatic mutation profile of tumor specimen ALCH-B73V-TTP1-A (aliquot ALCH-B73V-TTP1-A-4-0-D-A95Q-47) from ALCHEMIST case ALCH-B73V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,298 days).
Specimen ALCH-B73V-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 181cbb3a-b4be-4375-811b-34c6f6cbd3ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B73V-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B73V-NB1-A-1-0-D-A95Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/534e86d0-8f18-4668-9d25-ca9fd814d834

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by mutect2, varscan2
- ANKRD17 | c.3622G>C p.E1208Q | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58230066; called by muse, mutect2
- ANKRD30A | c.2552G>A p.R851K (on ENST00000611781; = p.R795K on NM_052997.2) | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100652884, COSV100653678; called by muse, mutect2
- DCX | c.210C>G p.Y70* | Nonsense Mutation (SNP) | VAF 17/257 reads (7%) | catalogued as COSV57568241, COSV57570199; called by muse, mutect2
- FOSL2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs763475600, COSV53105197; called by muse, mutect2
- IL18RAP | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99962504; called by muse, mutect2
- KLHL9 | c.81dup p.T28Yfs*14 | Frame Shift Ins (INS) | VAF 16/162 reads (10%) | catalogued as rs755553508; called by mutect2, pindel
- PAAF1 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100142394; called by muse, mutect2
- ZNF716 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554323431; called by muse, mutect2
- C4orf54 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GPALPP1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2
- LAIR2 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.134); called by muse, mutect2
- MAST2 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2
- PROSER1 | c.139T>A p.W47R | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WHAMM | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- EXOC8 | c.2121G>A p.L707= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as rs1181163553; called by muse, mutect2
- GARRE1 | c.303C>T p.F101= | Silent (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- MED25 | c.1617G>A p.Q539= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1383962758, COSV57207787; called by muse, mutect2
- MYO16 | c.1909C>T p.L637= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV51819028; called by muse, mutect2
- PREX1 | c.2883G>A p.P961= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs368665525, COSV64255201; called by muse, mutect2
- SLC37A3 | c.927C>T p.F309= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
